Somatic mutation profile of tumor specimen TCGA-CJ-4899-01A (aliquot TCGA-CJ-4899-01A-01D-1462-08) from TCGA case TCGA-CJ-4899, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 42.8 years (15,637 days).
Specimen TCGA-CJ-4899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2919b59a-7b3c-40c1-a7a7-d585ada1f32b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4899-11A (Solid Tissue Normal), aliquot TCGA-CJ-4899-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/557e84fa-023c-4c8c-bff7-a4ba5033d4a6

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 17, Silent 9, Frame Shift Del 3, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBOX1 | c.935C>A p.A312D | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54191738; called by muse, varscan2
- BPIFB4 | c.1665C>A p.N555K | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as COSV100971532, COSV64951543; called by muse, mutect2, varscan2
- CDH2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV52284300; called by muse, mutect2, varscan2
- CHD6 | c.7481G>A p.G2494E | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749828766, COSV64691957; called by muse, mutect2, varscan2
- COL3A1 | c.3976del p.V1326Ffs*61 | Frame Shift Del (DEL) | VAF 33/231 reads (14%) | catalogued as COSV58582927; called by mutect2, pindel, varscan2
- IGF2R | c.1699T>G p.S567A | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV63630051; called by muse, mutect2, varscan2
- OR4D1 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52125420; called by muse, mutect2, varscan2
- PAF1 | c.210C>G p.H70Q | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV55394838; called by muse, mutect2, varscan2
- SLC47A1 | c.1204A>G p.S402G | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs777906906, COSV54501959; called by muse, mutect2, varscan2
- SLC6A14 | c.769G>T p.G257* | Nonsense Mutation (SNP) | VAF 9/131 reads (7%) | catalogued as COSV100903131, COSV64147495; called by muse, mutect2
- SNU13 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.855); catalogued as COSV53238318; called by muse, mutect2, varscan2
- STAB1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201076394, COSV100401793, COSV58738453; called by muse, mutect2
- TONSL | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as rs763201864, COSV68048566; called by muse, mutect2, varscan2
- TRPM7 | c.3018T>G p.I1006M | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV57918105; called by muse, mutect2, varscan2
- TSGA10IP | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV73245325; called by muse, mutect2, varscan2
- UBE4A | c.3013G>C p.V1005L (on ENST00000252108 / NM_001204077.2; = p.V1012L on NM_004788.4) | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52804891; called by muse, mutect2, varscan2
- USP50 | c.468A>T p.K156N (on ENST00000616326; = p.K147N on NM_203494.5) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as COSV73214084; called by muse, mutect2, varscan2
- VIL1 | c.1639G>C p.V547L | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50290111; called by muse, mutect2
- WNT3A | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV52731853; called by muse, mutect2, varscan2
- AC244197.3 | c.169del p.M57Wfs*12 | Frame Shift Del (DEL) | VAF 81/228 reads (36%) | called by mutect2, pindel, varscan2
- ESCO1 | c.476dup p.C160Vfs*2 | Frame Shift Ins (INS) | VAF 75/458 reads (16%) | called by mutect2, pindel, varscan2
- OBSL1 | c.4081_4086del p.K1361_L1362del | In Frame Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- SPAG5 | c.978del p.D327Mfs*24 | Frame Shift Del (DEL) | VAF 37/170 reads (22%) | called by mutect2, pindel, varscan2
- AKT1S1 | c.495C>T p.P165= (on ENST00000344175 / NM_001098633.4; = p.P185= on NM_032375.5) | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs368386866, COSV59276444; called by muse, mutect2, varscan2
- DTWD2 | c.237T>C p.C79= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as COSV58367252; called by muse, mutect2, varscan2
- LTBP2 | c.4092G>A p.V1364= | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as rs1005213228, COSV56209858; called by muse, mutect2, varscan2
- MAT2A | c.429T>C p.T143= | Silent (SNP) | VAF 52/283 reads (18%) | catalogued as COSV52088879; called by muse, mutect2, varscan2
- POGK | c.351C>G p.T117= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV63311824; called by muse, mutect2
- PRAMEF1 | c.630G>A p.L210= | Silent (SNP) | VAF 142/876 reads (16%) | catalogued as COSV60011047; called by muse, varscan2
- SEMG1 | c.234G>A p.Q78= | Silent (SNP) | VAF 11/208 reads (5%) | catalogued as COSV54873366; called by muse, mutect2
- TASOR2 | c.3693A>C p.S1231= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV60168097; called by muse, mutect2
- UBN2 | c.1899T>A p.S633= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV56032271; called by muse, mutect2, varscan2
